Somatic mutation profile of tumor specimen 0DDCAM from CCDI case PBBKIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 4.8 years (1,752 days).
Specimen 0DDCAM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7acc3c81-c4a9-458f-a0a4-578c376bcc95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDCAN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc0b083-4379-403e-934e-de7f1792d0fd

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLEKHF1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 106/184 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1302128957; called by muse, varscan2
- TEX2 | c.2142C>G p.I714M | Missense Mutation (SNP) | VAF 122/562 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, varscan2
- IL4I1 | c.1497C>T p.R499= | Silent (SNP) | VAF 67/295 reads (23%) | catalogued as rs775033645; called by muse, varscan2
- BICDL2 | c.763-65C>A | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, varscan2
